Somatic mutation profile of tumor specimen 0DDRO0 from CCDI case PBBPDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxoid liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 18.8 years (6,875 days).
Specimen 0DDRO0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a664bc81-e982-4aa9-9ca3-77a145072fb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDRO1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d04ecd9-a370-493d-a641-40b5d9d9bbe9

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.3934_3953delinsCAG p.V1312Qfs*2 | Frame Shift Del (DEL) | VAF 97/439 reads (22%) | called by pindel, varscan2*
- ELP1 | c.1190A>T p.N397I | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- UBR5 | c.6688G>A p.E2230K | Missense Mutation (SNP) | VAF 191/471 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZFHX4 | c.240dup p.P81Tfs*22 | Frame Shift Ins (INS) | VAF 198/559 reads (35%) | called by mutect2, pindel, varscan2
- BRWD3 | c.4317G>A p.Q1439= | Silent (SNP) | VAF 190/567 reads (34%) | called by muse, mutect2, varscan2
- IL17A | c.294C>T p.G98= | Silent (SNP) | VAF 170/468 reads (36%) | called by muse, mutect2, varscan2
- PCLO | c.5398A>C p.R1800= | Silent (SNP) | VAF 193/520 reads (37%) | called by muse, mutect2, varscan2
- PLAU | c.798C>T p.S266= | Silent (SNP) | VAF 258/708 reads (36%) | catalogued as rs767978842, COSV101032270; called by muse, mutect2, varscan2
- KCNAB2 | c.201+51G>A | Intron (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
